Surgical pathology report (de-identified scan), TCGA case TCGA-3A-A9I5, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-3A-A9I5-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

Final Diagnosis

- A. GALLBLADDER:
Gallbladder with no significant pathologic abnormality recognized.
- B. HEAD OF PANCREAS, DISTAL STOMACH, PORTION OF DUODENUM, STANDARD PANCREATODUODENECTOMY:
Intraductal papillary mucinous neoplasm, with high grade dysplasia, pancreatobiliary type, of the main pancreatic duct, with microscopic foci of invasive ductal adenocarcinoma, well-differentiated, largest microscopic focus is 1.0 cm.
Uncinate, common bile duct, pancreatic, proximal gastric and distal duodenal resection margins are all free of malignancy. See Key Pathological Findings.

I, _____ the attending pathologist, personally reviewed the entire case and rendered the final diagnosis. Electronically Signed out by _____

Comment

The intraductal papillary mucinous neoplasm with high grade dysplasia is seen to involve the main pancreatic duct with extension into the side branches. In the area of the Ampulla where the pancreatic duct enters the duodenum, the neoplastic epithelium is seen to extend into the duodenum. In this area, also there is microscopic invasion of the pancreatic duct wall. However, there is not invasion into the wall of the duodenum.

Key Pathological Findings

B: Pancreas-Exocrine Synoptic Data

SPECIMEN TYPE: Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy

TUMOR SITE:

Pancreatic head

TUMOR SIZE: Invasive:

1.0 cm

TUMOR SIZE: Cystic:

3.0 cm

*OTHER ORGANS RESECTED::

*Duodenum

*Distal Stomach

Ductal adenocarcinoma

HISTOLOGIC GRADE: G1: Well differentiated

EXTENT OF INVASION - PRIMARY TUMOR: Tumor limited to pancreas

PRIMARY TUMOR (pT): pT1: Tumor limited to the pancreas, 2 cm or less in greatest dimension

REGIONAL LYMPH NODES (pN): pN0: No regional lymph node metastasis

Number examined: 13

Number involved: 0

DISTANT METASTASIS (pM): pMX: Cannot be assessed

*ICD-O-3
Adenocarcinoma, duct NOS 8500/3
Site: Pancreas head C25.0
4/16/14*

[page 2 of 3]
MARGINS:

Margins free of tumor

*VENOUS (LARGE VESSEL) INVASION (V): *Absent

*LYMPHATIC (SMALL VESSEL) INVASION (L): *Absent

*PERINEURAL INVASION: *Present

***ADDITIONAL PATHOLOGIC FINDINGS:**

*Chronic pancreatitis

Intraductal papillary mucinous neoplasm, with high grade dysplasia

Specimen(s) Received

A GALLBLADDER

B WHIPPLE 3FS

Clinical History

PANCREATIC CANCER.

Preoperative Diagnosis

Not given.

Frozen Section Diagnosis

FSB WHIPPLE:

FSB1 Bile duct margin, negative.

FSB2 Pancreatic margin, negative.

FSB3 Gastric margin, negative.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by Dr.

Intraoperative Consultation

TOUCH PREP.

____ MARGIN:

Favor negative.

Gross Description

A. Specimen A is received fresh labeled "gallbladder." The specimen consists of a club shaped measuring 7.0 x 4.0 x 2.5 cm. The external surface is gray-tan with a small amount of adherent fibroadipose tissue. The bile duct is identified and is probe-patent measuring 0.5 cm in length. On opening, no calculi is grossly appreciated. The specimen contains a moderate amount of green _____ bile. The wall measures 0.2 cm at its greatest thickness. The mucosal surface is green-yellow and velvet like. No tissue is submitted to the tissue procurement laboratory. Representative sections are

[page 3 of 3]
submitted as A1.

B. Specimen B is received fresh for OR consult labeled "Whipple specimen, frozen section." The specimen consists of the head of the pancreas, a portion of the duodenum, and a portion of the stomach. The entire specimen measures 21.0 x 7.0 x 3.5 cm. The duodenum measures 14.0 cm in length. The serosa of the duodenum is gray-tan and somewhat roughened. On opening the duodenum, a moderate amount of bile stained material is expelled. No polyps or nodularities grossly appreciated on the mucosal surface. The ampulla of Vater is not prominent. The pancreas measures 5.0 x 3.5 x 2.5 cm. On palpating the pancreas, a mass is grossly appreciated. The pancreatic duct is not probe-patent and grossly appears to be involved by tumor. Where the pancreatic duct empties into the duodenum, the duct grossly presents with a fish-mouth appearance. On sectioning the pancreas, the mass measures 3.0 x 2.5 x 1.5 cm. The mass comes to within 1.0 cm of the pancreatic margin of resection. The mass grossly appears to involve the duodenum and the common bile duct, but grossly does not appear to extend to the attached stomach. No normal pancreatic parenchyma is grossly appreciated. The attached stomach measures 7.0 cm along the greater curvature and 4.0 cm along the lesser curvature. The serosa is tan-pink and smooth. The mucosa is tan and exhibits normal mucosal folds. Sectioning of the attached adipose tissue isolates 3 possible lymph nodes at the head of the pancreas. No additional lymph nodes are isolated. All attached adipose tissue is submitted for processing. A representative section of the tumor is submitted to tissue procurement laboratory. Three representative frozen sections are taken and submitted as FSB1-3. Permanent representative sections are submitted as:

- B4: Mirror image of tissue submitted to tissue procurement laboratory
- B5: Tangential peritoneal margin of resection
- B6: Pancreatic duct opening into the duodenum (fish mouth)
- B7: Pancreatic duct within the pancreas showing relationship to tumor
- B8: Tumor showing its relationship to duodenum
- B9: Tumor showing its relationship to the common bile duct
- B10-B11: Additional sections of tumor
- B12: Ampulla of Vater
- B13: Grossly unremarkable duodenum
- B14: Grossly unremarkable stomach
- B15: Possible lymph nodes from the head of pancreas
- B16-B22: All adipose tissue from head of pancreas
- B23-B24: All adipose tissue from the lesser curvature
- B25-B40: All adipose tissue attached to greater curvature

Source: NCI Genomic Data Commons file 832831f8-9ec7-4f98-8acc-b6b85bb78eaf (TCGA-3A-A9I5.3F27C6DB-101D-4522-9C7D-23B7DD54ADCB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).